Somatic mutation profile of tumor specimen TCGA-DM-A1HA-01A (aliquot TCGA-DM-A1HA-01A-11D-A152-10) from TCGA case TCGA-DM-A1HA, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-DM-A1HA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95c6ad69-c289-4429-92fb-47f9b922b1c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DM-A1HA-10A (Blood Derived Normal), aliquot TCGA-DM-A1HA-10A-01D-A152-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6142b30-187c-4d7d-89a4-6ae7c4c88ce2

The open-access MAF lists 156 somatic variants for this specimen: 122 protein-altering or splice-affecting, 31 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 103, Silent 31, Nonsense Mutation 9, Frame Shift Ins 3, Frame Shift Del 3, Splice Site 2, Splice Region 2, RNA 1, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4241del p.V1414Efs*5 | Frame Shift Del (DEL) | VAF 55/120 reads (46%) | catalogued as rs1554085659, COSV57325736, COSV57326393; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 227/239 reads (95%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 34/39 reads (87%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.4298T>C p.V1433A | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as COSV52635733, COSV52640917; called by muse, mutect2, varscan2
- AC104389.6 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 70/174 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs867270501, COSV57962955; called by muse, varscan2
- AGTPBP1 | c.2029C>T p.Q677* (on ENST00000357081 / NM_001330701.2; = p.Q637* on NM_015239.2) | Nonsense Mutation (SNP) | VAF 19/46 reads (41%) | catalogued as COSV61268683; called by muse, mutect2, varscan2
- AIMP2 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747974072, COSV52236201; called by muse, mutect2, varscan2
- ANAPC5 | c.1550A>G p.D517G | Missense Mutation (SNP) | VAF 70/73 reads (96%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99946552; called by muse, mutect2, varscan2
- AP1S3 | c.115A>T p.I39F | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV57509471; called by muse, mutect2, varscan2
- APBB1 | c.2032G>T p.A678S | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.836); catalogued as COSV54966400; called by muse, mutect2, varscan2
- BCL6B | c.337G>T p.A113S | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT tolerated (0.41); PolyPhen benign (0.063); catalogued as COSV53426304; called by muse, mutect2, varscan2
- BCOR | c.4123C>T p.R1375W (on ENST00000378444 / NM_001123385.2; = p.R1341W on NM_017745.6) | Missense Mutation (SNP) | VAF 81/89 reads (91%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV60700149; called by muse, mutect2, varscan2
- BICRA | c.1550A>G p.N517S | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.134); catalogued as COSV101194502; called by muse, mutect2, varscan2
- BMPR1B | c.245G>C p.R82P | Missense Mutation (SNP) | VAF 135/283 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as COSV52774850; called by muse, mutect2, varscan2
- CAMKK2 | c.548A>C p.Y183S | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV61212932; called by muse, mutect2, varscan2
- CCDC88C | c.71_81delinsACG p.F24Yfs*39 | Frame Shift Del (DEL) | VAF 21/28 reads (75%) | catalogued as COSV66231699; called by pindel, varscan2*
- CCRL2 | c.163G>T p.D55Y | Missense Mutation (SNP) | VAF 55/110 reads (50%) | SIFT tolerated (1); PolyPhen possibly damaging (0.897); catalogued as COSV62193206; called by muse, mutect2, varscan2
- CDH9 | c.1630+1G>C p.X544_splice | Splice Site (SNP) | VAF 53/105 reads (50%) | catalogued as COSV50252786; called by muse, mutect2, varscan2
- CHRM2 | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs1432230108, COSV57765651; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLEC11A | c.948C>A p.Y316* | Nonsense Mutation (SNP) | VAF 21/45 reads (47%) | catalogued as COSV51573507; called by muse, mutect2, varscan2
- COLEC10 | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 79/86 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372901535; called by muse, mutect2, varscan2
- CRISPLD1 | c.726A>T p.K242N | Missense Mutation (SNP) | VAF 147/154 reads (95%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as COSV51544395; called by muse, mutect2, varscan2
- CROCC | c.1621C>T p.R541C | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV65010039; called by muse, mutect2, varscan2
- CYP26B1 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs770223566, COSV50010773; called by muse, mutect2, varscan2
- CYP4A11 | c.682G>T p.V228F | Missense Mutation (SNP) | VAF 75/164 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as rs753851320, COSV60222102; called by muse, mutect2, varscan2
- DIP2C | c.4117G>A p.E1373K | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55146414; called by muse, mutect2, varscan2
- DNAH5 | c.9521C>T p.T3174M | Missense Mutation (SNP) | VAF 79/159 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757354117, COSV54229730; called by muse, mutect2, varscan2
- DNAH8 | c.5138G>A p.R1713H | Missense Mutation (SNP) | VAF 178/191 reads (93%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs758923038, COSV59423705; called by muse, mutect2, varscan2
- DNAJB8 | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as rs1435907907, COSV59878028, COSV59879377; called by muse, mutect2, varscan2
- DNER | c.661C>A p.P221T | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs1262052231, COSV59160369; called by muse, mutect2, varscan2
- DSTN | c.308dup p.L103Ffs*12 | Frame Shift Ins (INS) | VAF 71/306 reads (23%) | catalogued as rs750962255; called by mutect2, varscan2
- FAT2 | c.1356C>A p.N452K | Missense Mutation (SNP) | VAF 57/119 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55813419; called by muse, mutect2, varscan2
- FBXL7 | c.991G>A p.V331I | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.036); catalogued as rs762341690, COSV61641347; called by muse, mutect2, varscan2
- FRG2B | c.460G>T p.G154W | Missense Mutation (SNP) | VAF 200/252 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101423549, COSV71042763, COSV71042956; called by muse, varscan2
- FZD7 | c.316T>C p.Y106H | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53808298; called by muse, mutect2, varscan2
- GMPPA | c.592T>C p.F198L | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as rs773715630, COSV58006033; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPR27 | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 36/60 reads (60%) | SIFT tolerated (0.32); PolyPhen benign (0.058); catalogued as rs1412434806, COSV55203061; called by muse, mutect2, varscan2
- GRIK3 | c.1994G>A p.R665H | Missense Mutation (SNP) | VAF 65/153 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs569239695, COSV66135692; called by muse, mutect2, varscan2
- HMGB4 | c.353G>T p.W118L | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as COSV53880525, COSV53885718; called by muse, mutect2, varscan2
- HTR2A | c.1387G>A p.G463R | Missense Mutation (SNP) | VAF 210/420 reads (50%) | SIFT tolerated (0.53); PolyPhen benign (0.014); catalogued as rs749275325, COSV66326650, COSV66326676; called by muse, mutect2, varscan2
- IFT81 | c.74C>T p.T25M | Missense Mutation (SNP) | VAF 184/195 reads (94%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as rs889742464, COSV54360611; called by muse, mutect2, varscan2
- IGSF9B | c.1907C>T p.P636L | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.843); catalogued as rs1460729525, COSV58063995; called by muse, mutect2, varscan2
- IL17RB | c.901G>T p.A301S | Missense Mutation (SNP) | VAF 51/51 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.419); catalogued as COSV55472017; called by muse, mutect2, varscan2
- IL6 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 40/67 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs1326968679, COSV51732270, COSV51732649; called by muse, mutect2, varscan2
- IMPG1 | c.1981C>T p.R661C | Missense Mutation (SNP) | VAF 96/101 reads (95%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs761693136, COSV64054340; called by muse, mutect2, varscan2
- IMPG2 | c.2224A>T p.I742F | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51973642; called by muse, mutect2, varscan2
- IPO11 | c.2257G>C p.E753Q | Missense Mutation (SNP) | VAF 41/44 reads (93%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV57572145; called by muse, mutect2, varscan2
- ITGA10 | c.2987A>T p.H996L | Missense Mutation (SNP) | VAF 71/77 reads (92%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as COSV65196069; called by muse, mutect2, varscan2
- KCNQ2 | c.1997C>T p.P666L (on ENST00000359125 / NM_172107.4; = p.P638L on NM_004518.6) | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as rs762130930, COSV60540199; called by muse, mutect2, varscan2
- KCNT2 | c.3031C>T p.R1011W | Missense Mutation (SNP) | VAF 190/202 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs760737863, COSV54064723; called by muse, mutect2, varscan2
- KIAA0586 | c.1078C>T p.H360Y (on ENST00000619416 / NM_001244190.2; = p.H375Y on NM_014749.5) | Missense Mutation (SNP) | VAF 59/155 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV54171263; called by muse, mutect2, varscan2
- KIAA1755 | c.3449G>A p.R1150H | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs140875990; called by muse, mutect2, varscan2
- KIFC1 | c.1379G>T p.S460I | Missense Mutation (SNP) | VAF 36/36 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV65737306; called by muse, mutect2, varscan2
- KNTC1 | c.496A>T p.N166Y | Missense Mutation (SNP) | VAF 138/304 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV61078898; called by muse, mutect2, varscan2
- KRT39 | c.1288G>T p.E430* | Nonsense Mutation (SNP) | VAF 50/106 reads (47%) | catalogued as COSV62916839; called by muse, mutect2, varscan2
- LRP2 | c.456T>G p.C152W | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99790566; called by muse, mutect2, varscan2
- LRP2 | c.455G>A p.C152Y | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99790568; called by muse, mutect2, varscan2
- LRP4 | c.546T>C p.C182= | Splice Region (SNP) | VAF 5/35 reads (14%) | catalogued as COSV101066916; called by muse, mutect2, varscan2
- MAP10 | c.1462C>T p.P488S | Missense Mutation (SNP) | VAF 73/79 reads (92%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.55); catalogued as COSV69362755; called by muse, mutect2, varscan2
- MOV10 | c.2279G>A p.R760Q | Missense Mutation (SNP) | VAF 26/28 reads (93%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as COSV53516716; called by muse, mutect2, varscan2
- MYO1F | c.1454C>T p.A485V | Missense Mutation (SNP) | VAF 48/53 reads (91%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs367720693; called by muse, mutect2, varscan2
- NEK10 | c.2505+1G>A p.X835_splice | Splice Site (SNP) | VAF 103/115 reads (90%) | catalogued as rs768160759, COSV55355123; called by muse, mutect2, varscan2
- NMUR2 | c.672C>A p.F224L | Missense Mutation (SNP) | VAF 71/139 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54917093, COSV54919306; called by muse, varscan2
- NOX4 | c.1259C>T p.S420L | Missense Mutation (SNP) | VAF 113/241 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as COSV54446995; called by muse, mutect2, varscan2
- NPAP1 | c.1050G>C p.E350D | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.37); PolyPhen benign (0.143); catalogued as rs757583074, COSV100276318; called by muse, mutect2
- OR6T1 | c.860C>G p.P287R | Missense Mutation (SNP) | VAF 68/151 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100189625, COSV58305658; called by muse, mutect2, varscan2
- P3H4 | c.1039G>T p.E347* | Nonsense Mutation (SNP) | VAF 38/67 reads (57%) | catalogued as COSV62679751; called by muse, mutect2, varscan2
- PAPPA2 | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.534); catalogued as rs758781900, COSV62773172; called by muse, mutect2, varscan2
- PCDH11X | c.1792G>T p.D598Y | Missense Mutation (SNP) | VAF 182/231 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100015854; called by muse, mutect2, varscan2
- PCDHA9 | c.2053G>T p.G685C | Missense Mutation (SNP) | VAF 106/208 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.832); catalogued as COSV65323547; called by muse, mutect2
- PCDHGA5 | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.676); catalogued as rs374170303; called by muse, mutect2, varscan2
- PCLO | c.9166G>A p.A3056T | Missense Mutation (SNP) | VAF 62/219 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs933510861, COSV61616581; called by muse, mutect2, varscan2
- PISD | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 38/43 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs373015840, COSV100338712; called by muse, mutect2, varscan2
- PLCH2 | c.3681G>C p.R1227S | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.007); catalogued as COSV53939255; called by muse, mutect2, varscan2
- PLXDC2 | c.889C>T p.R297* | Nonsense Mutation (SNP) | VAF 19/45 reads (42%) | catalogued as rs749464992, COSV65900855, COSV65903364; called by muse, mutect2, varscan2
- POM121L12 | c.756G>C p.W252C | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.557); catalogued as COSV68692244, COSV68694689; called by muse, varscan2
- POM121L12 | c.815C>T p.T272M | Missense Mutation (SNP) | VAF 28/37 reads (76%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.614); catalogued as COSV68692247; called by muse, varscan2
- PRKAB1 | c.260G>A p.G87D | Missense Mutation (SNP) | VAF 74/83 reads (89%) | SIFT deleterious (0.05); PolyPhen benign (0.053); catalogued as COSV57554668, COSV57554715; called by muse, mutect2, varscan2
- PWWP3A | c.1691G>T p.R564L (on ENST00000627377; = p.R563L on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60900847; called by muse, mutect2, varscan2
- RASGEF1A | c.110A>G p.D37G | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100988739; called by muse, mutect2, varscan2
- RASGRP1 | c.517C>G p.Q173E | Missense Mutation (SNP) | VAF 61/69 reads (88%) | SIFT tolerated (0.26); PolyPhen benign (0.096); catalogued as COSV60363680, COSV60365292; called by muse, mutect2, varscan2
- RASSF2 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 26/27 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs747554035, COSV65081666; called by muse, mutect2, varscan2
- RING1 | c.743G>T p.S248I | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.5); catalogued as COSV63002283; called by muse, mutect2, varscan2
- RNF145 | c.1626G>A p.Q542= (on ENST00000424310 / NM_001199383.2; = p.Q570= on NM_144726.2) | Splice Region (SNP) | VAF 80/190 reads (42%) | catalogued as COSV50864376; called by muse, mutect2, varscan2
- RSPH10B2 | c.1502C>T p.A501V | Missense Mutation (SNP) | VAF 484/1462 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99786428; called by muse, varscan2
- SBF1 | c.5464G>A p.D1822N | Missense Mutation (SNP) | VAF 56/62 reads (90%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as rs1052849995, COSV53290215; called by muse, mutect2, varscan2
- SCAF8 | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 69/147 reads (47%) | catalogued as COSV65790032; called by muse, mutect2, varscan2
- SCN1A | c.5822C>T p.T1941M (on ENST00000303395 / NM_001202435.3; = p.T1930M on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/176 reads (44%) | SIFT tolerated (0.6); PolyPhen benign (0.075); catalogued as rs756845310, COSV57660387; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SDF4 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as rs778380110, COSV55417693; called by muse, mutect2, varscan2
- SEL1L2 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 78/84 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53148109; called by muse, mutect2, varscan2
- SIAH3 | c.127A>T p.N43Y | Missense Mutation (SNP) | VAF 84/173 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV68551363; called by muse, mutect2, varscan2
- SLC16A14 | c.1400C>T p.T467M | Missense Mutation (SNP) | VAF 46/89 reads (52%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.927); catalogued as rs201925005, COSV54616814; called by muse, mutect2, varscan2
- SLC2A3 | c.928G>A p.G310S | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs149866146; called by muse, mutect2, varscan2
- SLC6A2 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.481); catalogued as rs147833183; called by muse, mutect2, varscan2
- SLCO6A1 | c.1447G>T p.A483S | Missense Mutation (SNP) | VAF 143/343 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs368808696; called by muse, mutect2, varscan2
- SPICE1 | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 95/211 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs374212056, COSV55620762; called by muse, varscan2
- SPRR1B | c.184C>A p.P62T | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61067429, COSV61068080; called by muse, mutect2, varscan2
- SPTY2D1 | c.859A>T p.R287W | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV60472888; called by muse, varscan2
- STAT3 | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 92/183 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52883978; called by muse, mutect2, varscan2
- SVIL | c.6248C>T p.A2083V (on ENST00000355867 / NM_021738.3; = p.A1657V on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as rs962091794, COSV63443905; called by muse, mutect2, varscan2
- TBX20 | c.1007C>T p.S336L | Missense Mutation (SNP) | VAF 68/292 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.916); catalogued as COSV101282437; called by muse, mutect2, varscan2
- TF | c.817C>T p.R273* | Nonsense Mutation (SNP) | VAF 47/94 reads (50%) | catalogued as rs902231111, COSV53917195; called by muse, mutect2, varscan2
- TFAP2B | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 83/94 reads (88%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); catalogued as COSV53825223; called by muse, mutect2, varscan2
- THBS2 | c.1618C>T p.R540C | Missense Mutation (SNP) | VAF 94/103 reads (91%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.606); catalogued as rs781588133, COSV64677120; called by muse, mutect2, varscan2
- TRIM65 | c.1308C>A p.H436Q | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53932329; called by muse, mutect2
- TRPM3 | c.2309G>A p.R770H (on ENST00000357533 / NM_001366142.2; = p.R613H on NM_020952.6) | Missense Mutation (SNP) | VAF 16/17 reads (94%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.454); catalogued as rs142609293; called by muse, mutect2, varscan2
- TSSK1B | c.357G>T p.Q119H | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66814826; called by muse, mutect2, varscan2
- TTN | c.12109G>T p.D4037Y (on ENST00000591111; = p.D3991Y on NM_003319.4) | Missense Mutation (SNP) | VAF 58/116 reads (50%) | catalogued as rs1177478241, COSV59893265; called by muse, mutect2, varscan2
- UBA6 | c.1739G>A p.R580H | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1284679469, COSV59175286, COSV59177903; called by muse, mutect2, varscan2
- USP22 | c.1256G>A p.R419Q | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.716); catalogued as rs1446920538, COSV54945542; called by muse, mutect2, varscan2
- VPREB3 | c.339C>G p.Y113* | Nonsense Mutation (SNP) | VAF 34/40 reads (85%) | catalogued as COSV50707398; called by muse, varscan2
- VPREB3 | c.229C>A p.H77N | Missense Mutation (SNP) | VAF 34/39 reads (87%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV50707402; called by muse, mutect2, varscan2
- VPS26A | c.981G>A p.M327I | Missense Mutation (SNP) | VAF 44/188 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs140007940; called by muse, mutect2
- VWA8 | c.2473G>A p.G825R | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs753556286, COSV55692220; called by muse, mutect2, varscan2
- WDTC1 | c.1586G>A p.R529H (on ENST00000319394 / NM_001276252.2; = p.R528H on NM_015023.5) | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60087165, COSV60089078; called by muse, mutect2, varscan2
- XIRP2 | c.8240A>T p.Q2747L (on ENST00000628543; = p.Q2922L on NM_152381.6) | Missense Mutation (SNP) | VAF 109/238 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV54683234, COSV99742434; called by muse, mutect2, varscan2
- ZFP36L2 | c.442C>T p.Q148* | Nonsense Mutation (SNP) | VAF 38/80 reads (48%) | catalogued as COSV56697090; called by muse, mutect2, varscan2
- ZFP64 | c.94A>T p.I32F | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53796444; called by muse, mutect2, varscan2
- ZNF763 | c.78G>C p.R26S (on ENST00000358987 / NM_001367172.2; = p.R29S on NM_001012753.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 101/241 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV59687114; called by muse, mutect2, varscan2
- APC | c.2342_2351dup p.H785Qfs*6 | Frame Shift Ins (INS) | VAF 30/76 reads (39%) | called by mutect2, varscan2
- IFI16 | c.679dup p.I227Nfs*42 | Frame Shift Ins (INS) | VAF 94/218 reads (43%) | called by mutect2, varscan2
- PATE2 | c.108del p.K36Nfs*11 | Frame Shift Del (DEL) | VAF 46/106 reads (43%) | called by mutect2, varscan2
- ADGRA1 | c.1194C>T p.H398= | Silent (SNP) | VAF 13/14 reads (93%) | catalogued as rs140168806, COSV66924778; called by muse, mutect2, varscan2
- ALPI | c.1329G>A p.A443= | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as COSV55013464; called by muse, mutect2, varscan2
- ATP2B2 | c.1275C>T p.Y425= (on ENST00000352432; = p.Y391= on NM_001683.5) | Silent (SNP) | VAF 71/75 reads (95%) | catalogued as rs371159930; called by muse, mutect2, varscan2
- C2CD3 | c.1776C>T p.S592= | Silent (SNP) | VAF 27/54 reads (50%) | catalogued as rs751170568, COSV100487443, COSV58089665; called by muse, mutect2, varscan2
- CRHR1 | c.288C>T p.R96= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs781652857, COSV99524263; called by muse, mutect2, varscan2
- DNER | c.360C>G p.L120= | Silent (SNP) | VAF 30/69 reads (43%) | catalogued as COSV59160378; called by muse, varscan2
- DPF2 | c.930C>T p.T310= | Silent (SNP) | VAF 33/73 reads (45%) | catalogued as COSV52887869; called by muse, mutect2, varscan2
- GALNS | c.996A>G p.A332= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as COSV51935744; called by muse, varscan2
- INTS6L | c.822A>G p.V274= | Silent (SNP) | VAF 133/141 reads (94%) | catalogued as COSV66083655; called by muse, mutect2, varscan2
- KIAA0319 | c.1746G>A p.T582= | Silent (SNP) | VAF 53/56 reads (95%) | catalogued as rs771949795, COSV65496393; called by muse, mutect2, varscan2
- KIAA1522 | c.2922C>A p.V974= (on ENST00000373480 / NM_001198972.2; = p.V1033= on NM_020888.3) | Silent (SNP) | VAF 57/139 reads (41%) | catalogued as COSV99615233; called by muse, mutect2, varscan2
- LCE1F | c.318C>T p.C106= | Silent (SNP) | VAF 39/82 reads (48%) | catalogued as rs773642403, COSV57668757; called by muse, mutect2, varscan2
- LONRF2 | c.1515C>T p.A505= | Silent (SNP) | VAF 44/90 reads (49%) | catalogued as rs1463992354, COSV66539382; called by muse, mutect2, varscan2
- MYLK2 | c.1071G>T p.L357= | Silent (SNP) | VAF 29/97 reads (30%) | catalogued as COSV65658532; called by muse, mutect2, varscan2
- NAV2 | c.4209C>T p.N1403= (on ENST00000396087 / NM_001244963.2; = p.N1380= on NM_145117.5) | Silent (SNP) | VAF 31/56 reads (55%) | catalogued as rs1297496369, COSV60656539; called by muse, mutect2, varscan2
- PCDH10 | c.660G>T p.G220= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as rs762772902, COSV52087711, COSV99993476; called by muse, mutect2, varscan2
- PON3 | c.234G>A p.A78= | Silent (SNP) | VAF 112/306 reads (37%) | catalogued as rs377390399, COSV55697888; called by muse, mutect2, varscan2
- RAD51 | c.477C>T p.Y159= | Silent (SNP) | VAF 53/56 reads (95%) | catalogued as COSV51110997; called by muse, mutect2, varscan2
- RBAK-RBAKDN | c.456G>A p.T152= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs1164695943, COSV67759857; called by muse, mutect2, varscan2
- RNF213 | c.14400C>T p.N4800= | Silent (SNP) | VAF 26/50 reads (52%) | catalogued as rs772660885, COSV60390495; called by muse, mutect2, varscan2
- SEMA6A | c.636C>T p.H212= | Silent (SNP) | VAF 69/153 reads (45%) | catalogued as rs373510249; called by muse, mutect2, varscan2
- SLC2A5 | c.714C>T p.R238= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as rs766297608, COSV66235356; called by muse, mutect2, varscan2
- SLC45A1 | c.186G>A p.P62= | Silent (SNP) | VAF 29/65 reads (45%) | catalogued as rs752538342, COSV57093039; called by muse, mutect2, varscan2
- STK39 | c.813G>A p.A271= | Silent (SNP) | VAF 88/189 reads (47%) | catalogued as rs751028855, COSV63595813; called by muse, mutect2, varscan2
- SYCP2L | c.1554T>C p.S518= | Silent (SNP) | VAF 216/226 reads (96%) | catalogued as COSV51649982; called by muse, mutect2, varscan2
- TBX15 | c.528G>A p.V176= (on ENST00000369429 / NM_001330677.2; = p.V70= on NM_152380.3) | Silent (SNP) | VAF 60/111 reads (54%) | catalogued as rs764651852, COSV52867648; called by muse, mutect2, varscan2
- TFAP2D | c.264C>T p.D88= | Silent (SNP) | VAF 203/214 reads (95%) | catalogued as COSV50408497; called by muse, mutect2, varscan2
- TM6SF2 | c.435G>A p.L145= | Silent (SNP) | VAF 75/83 reads (90%) | catalogued as rs1453484857, COSV66984935; called by muse, mutect2, varscan2
- TTC21B | c.3627A>G p.Q1209= | Silent (SNP) | VAF 155/292 reads (53%) | catalogued as rs960827061, COSV54627809; called by muse, mutect2, varscan2
- VPREB3 | c.141C>T p.V47= | Silent (SNP) | VAF 25/26 reads (96%) | catalogued as COSV50707404; called by muse, mutect2, varscan2
- ZNF57 | c.1134G>A p.T378= | Silent (SNP) | VAF 56/60 reads (93%) | catalogued as rs764935606, COSV60982589; called by muse, mutect2, varscan2
- C9orf163 | n.1549C>A | RNA (SNP) | VAF 14/66 reads (21%) | called by muse, mutect2, varscan2
- CLEC18B | c.*1G>A | 3'UTR (SNP) | VAF 82/578 reads (14%) | catalogued as COSV100376174; called by muse, mutect2, varscan2
- WT1 | chr11:32438920 G>A | 5'Flank (SNP) | VAF 19/56 reads (34%) | catalogued as rs558752929; called by muse, mutect2, varscan2
